Somatic mutation profile of tumor specimen TCGA-34-2608-01A (aliquot TCGA-34-2608-01A-02W-0877-08) from TCGA case TCGA-34-2608, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.8 years (30,958 days).
Specimen TCGA-34-2608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d36c5579-90a9-49c3-9365-8b7db28448c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2608-11A (Solid Tissue Normal), aliquot TCGA-34-2608-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98aa5108-7b2e-4ce4-9958-a8d8529ef74b

The open-access MAF lists 141 somatic variants for this specimen: 103 protein-altering or splice-affecting, 33 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 33, Nonsense Mutation 6, RNA 3, Splice Region 2, Intron 2, Frame Shift Ins 2, Frame Shift Del 2, Nonstop Mutation 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 57/249 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER2 | c.1700C>A p.A567E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV63436269; called by muse, mutect2, varscan2
- AMY2B | c.315G>T p.G105= | Splice Region (SNP) | VAF 46/349 reads (13%) | catalogued as rs1189364425, COSV63714093; called by muse, mutect2, varscan2
- ATMIN | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55145202; called by muse, mutect2, varscan2
- ATP2B4 | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 81/492 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs940319491, COSV58174490; called by muse, mutect2, varscan2
- C16orf70 | c.1230dup p.R411Qfs*4 | Frame Shift Ins (INS) | VAF 15/110 reads (14%) | catalogued as rs539297455; called by mutect2, varscan2
- CCND1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV57119390; called by muse, mutect2, varscan2
- CDH8 | c.835+1G>A p.X279_splice | Splice Site (SNP) | VAF 15/132 reads (11%) | catalogued as COSV54849909, COSV54895721; called by muse, varscan2
- CHML | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs777997687, COSV100087852; called by muse, mutect2, varscan2
- CLEC9A | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV59531004; called by muse, mutect2, varscan2
- CLSTN3 | c.2434C>G p.H812D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56934151; called by muse, mutect2, varscan2
- COL12A1 | c.8911C>G p.P2971A | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV59389937; called by muse, mutect2
- CPAMD8 | c.2950C>T p.R984W (on ENST00000651564; = p.R937W on NM_015692.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs371527661; called by muse, mutect2, varscan2
- CSMD1 | c.9353C>A p.S3118Y (on ENST00000520002; = p.S3117Y on NM_033225.6) | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as COSV59284313; called by muse, mutect2
- CSMD3 | c.3403C>A p.R1135S (on ENST00000297405 / NM_001363185.1; = p.R1031S on NM_052900.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52108004; called by muse, mutect2, varscan2
- CTNNA3 | c.1465C>G p.H489D | Missense Mutation (SNP) | VAF 93/489 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV65551521, COSV65555140, COSV65598974; called by muse, mutect2, varscan2
- CUBN | c.4211G>T p.S1404I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64708363, COSV64729778; called by muse, mutect2
- DCC | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as COSV59085867; called by muse, mutect2
- DCN | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV50006111; called by muse, mutect2, varscan2
- DHX8 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 32/194 reads (16%) | catalogued as rs751521418, COSV52251003; called by muse, mutect2, varscan2
- DPPA4 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 60/398 reads (15%) | catalogued as COSV59509371; called by muse, mutect2, varscan2
- ENOX1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54888166, COSV99816728; called by muse, mutect2
- F13A1 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53553754; called by muse, mutect2, varscan2
- F13A1 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53553764; called by muse, mutect2, varscan2
- F5 | c.359G>C p.S120T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV63120907; called by muse, mutect2, varscan2
- FAT3 | c.12268C>A p.L4090I | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV53078757; called by muse, mutect2
- FSHR | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.335); catalogued as COSV58617975; called by muse, mutect2
- GALP | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV61999236; called by muse, mutect2, varscan2
- GPR158 | c.3242T>C p.I1081T | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV66265731; called by muse, mutect2, varscan2
- GRB10 | c.1641C>T p.C547= (on ENST00000398812; = p.C501= on NM_001001549.3) | Splice Region (SNP) | VAF 50/200 reads (25%) | catalogued as rs375434973; called by muse, mutect2, varscan2
- HERC5 | c.2683G>C p.D895H | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV52037403; called by muse, mutect2, varscan2
- HTR1A | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 40/453 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60499942, COSV60500518; called by muse, mutect2, varscan2
- IQGAP3 | c.4740G>T p.K1580N | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV63249536; called by muse, mutect2, varscan2
- KDM5C | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64762900; called by mutect2, varscan2
- KHDRBS2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs774551671, COSV55464127; called by mutect2, varscan2
- KIF1B | c.5180G>T p.R1727L (on ENST00000377086 / NM_001365952.1; = p.R1681L on NM_015074.3) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55803801; called by muse, mutect2
- LGSN | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV65726294; called by muse, mutect2
- LIG3 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV52005943; called by muse, mutect2, varscan2
- LRP2 | c.8225C>A p.S2742* | Nonsense Mutation (SNP) | VAF 40/341 reads (12%) | catalogued as COSV55541741; called by muse, mutect2, varscan2
- MMD2 | c.782C>T p.P261L (on ENST00000404774 / NM_001100600.2; = p.P237L on NM_198403.4) | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV68659764; called by muse, mutect2, varscan2
- MYH15 | c.3640G>C p.E1214Q | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56304697; called by muse, mutect2, varscan2
- MYL1 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV58974200; called by muse, mutect2, varscan2
- NBAS | c.4320G>T p.K1440N | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV55713253; called by muse, mutect2, varscan2
- NELL2 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV61569541; called by muse, mutect2, varscan2
- NOX3 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763222728, COSV50148772; called by muse, varscan2
- NPAS4 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60648942; called by muse, mutect2
- NPHP4 | c.1020A>T p.R340S | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65393264; called by muse, mutect2
- NR1H3 | c.1344A>T p.*448Cext*27 | Nonstop Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV60620694; called by muse, mutect2, varscan2
- OR2M4 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 77/568 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100141494, COSV60707288; called by muse, mutect2, varscan2
- OR4C16 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 95/1212 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs150706012, COSV58940789; called by muse, mutect2
- PCDH10 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV52087894; called by muse, mutect2, varscan2
- PCDH11X | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100008984; called by mutect2, varscan2
- PCDHA1 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as COSV65372753; called by muse, mutect2
- PCDHB6 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV99169949; called by muse, varscan2
- PKHD1 | c.375T>G p.D125E | Missense Mutation (SNP) | VAF 89/844 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as rs749231751, COSV61861712; called by muse, mutect2, varscan2
- PPP1R3C | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV53287670; called by muse, mutect2, varscan2
- PRAMEF19 | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 62/600 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs2101625; called by muse, mutect2, varscan2
- PRKN | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as CM1511367, COSV58203608; called by muse, mutect2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PXDN | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV53232035; called by muse, mutect2
- RAB6B | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53312195; called by muse, mutect2, varscan2
- RDH10 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53581343; called by muse, mutect2, varscan2
- RPP25L | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52406383; called by muse, varscan2
- RYR2 | c.2440C>T p.L814F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV63663894; called by muse, mutect2, varscan2
- RYR3 | c.6406C>A p.P2136T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66778813; called by muse, mutect2, varscan2
- SACM1L | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 216/486 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV66612485; called by muse, mutect2, varscan2
- SCN7A | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 38/273 reads (14%) | catalogued as COSV69268752; called by muse, mutect2, varscan2
- SERPINB5 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV101237614; called by muse, mutect2, varscan2
- SGSM1 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 54/648 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766572191, COSV68508829; called by muse, mutect2
- SLC12A6 | c.2442A>G p.I814M (on ENST00000354181 / NM_001365088.1; = p.I763M on NM_005135.2) | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.211); catalogued as COSV51623036; called by muse, mutect2, varscan2
- SLC39A2 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751140614, COSV53868929; called by muse, mutect2, varscan2
- SRSF1 | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51964180; called by muse, mutect2, varscan2
- SSH2 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 59/411 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV52166891, COSV52182746; called by muse, mutect2, varscan2
- STON1 | c.1217C>A p.P406Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.063); catalogued as COSV59126478; called by muse, mutect2, varscan2
- TCHHL1 | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1260388944, COSV64284920; called by muse, mutect2, varscan2
- TENT4B | c.1560T>A p.D520E (on ENST00000561678 / NM_001365323.2; = p.D505E on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/571 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.033); catalogued as COSV62546388; called by muse, mutect2, varscan2
- TEX47 | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51878241; called by muse, mutect2
- TEX47 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99787275; called by muse, mutect2
- TLN2 | c.4422G>T p.Q1474H | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60885827; called by muse, mutect2
- TMC3 | c.1467C>A p.S489R | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1486775230, COSV63922243; called by muse, mutect2, varscan2
- TMEM131 | c.3577A>T p.S1193C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV51770444; called by muse, mutect2
- TOM1 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65897416; called by muse, mutect2, varscan2
- TRIML1 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369262775; called by muse, mutect2
- TTN | c.81059T>C p.V27020A (on ENST00000591111; = p.V19596A on NM_003319.4) | Missense Mutation (SNP) | VAF 22/272 reads (8%) | PolyPhen benign (0.082); catalogued as COSV59899643; called by muse, mutect2
- TTN | c.10658T>C p.F3553S (on ENST00000591111; = p.F3507S on NM_003319.4) | Missense Mutation (SNP) | VAF 42/223 reads (19%) | catalogued as COSV59899681; called by muse, mutect2, varscan2
- UBE3B | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV55091427; called by muse, mutect2
- WDR72 | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 29/161 reads (18%) | catalogued as COSV100854286, COSV64741937; called by muse, mutect2, varscan2
- XDH | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65147019, COSV65147868; called by muse, mutect2, varscan2
- ZBTB43 | c.609T>G p.H203Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV65094415; called by muse, mutect2, varscan2
- ZFP91 | c.1135C>G p.R379G | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60157005; called by muse, mutect2
- ZNF341 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV61006068; called by muse, varscan2
- ZNF676 | c.107A>T p.N36I (on ENST00000650058; = p.N4I on NM_001001411.3) | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV68092241; called by muse, mutect2, varscan2
- ZNF831 | c.4607A>C p.E1536A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV64037653; called by muse, mutect2, varscan2
- CDH18 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- CSRNP2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2
- GDAP2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GIGYF2 | c.3734C>A p.T1245N | Missense Mutation (SNP) | VAF 22/523 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.326); called by muse, mutect2
- LARP4B | c.1714_1751del p.S572Lfs*24 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- MAPK9 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2
- SLITRK1 | c.1432_1433insACA p.L478delinsHI | In Frame Ins (INS) | VAF 13/63 reads (21%) | called by mutect2, varscan2
- TRIP11 | c.5421del p.S1808Afs*25 | Frame Shift Del (DEL) | VAF 107/603 reads (18%) | called by mutect2, pindel, varscan2
- UBAP1 | c.1443G>T p.L481F | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB20 | c.809_812dup p.T272Rfs*23 (on ENST00000474710 / NM_001164342.2; = p.T199Rfs*23 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- ADGRA3 | c.2187C>T p.I729= | Silent (SNP) | VAF 54/750 reads (7%) | catalogued as COSV51560435; called by muse, mutect2
- ARF5 | c.408G>T p.V136= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as COSV50000309; called by muse, mutect2
- ARHGEF38 | c.336T>C p.D112= | Silent (SNP) | VAF 49/353 reads (14%) | catalogued as rs146153509; called by muse, mutect2, varscan2
- C1orf174 | c.657C>T p.S219= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV59495816; called by muse, mutect2, varscan2
- CALD1 | c.304C>A p.R102= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV62645239; called by muse, mutect2
- CDC42BPG | c.705G>A p.P235= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs149531322; called by muse, mutect2, varscan2
- CSGALNACT1 | c.798C>T p.I266= | Silent (SNP) | VAF 210/1498 reads (14%) | catalogued as rs1340498278, COSV59974085; called by muse, mutect2, varscan2
- DDN | c.1284G>A p.E428= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60291588; called by mutect2, varscan2
- EPHA5 | c.1782C>T p.L594= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as rs1489893828, COSV56632328; called by muse, mutect2
- FNDC7 | c.711C>T p.S237= | Silent (SNP) | VAF 22/254 reads (9%) | catalogued as rs747899150, COSV54750931; called by muse, mutect2
- FUT8 | c.9A>G p.P3= | Silent (SNP) | VAF 38/402 reads (9%) | catalogued as COSV61280374; called by muse, mutect2
- GPR45 | c.777G>A p.L259= | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as COSV51522812; called by muse, mutect2, varscan2
- GRIK3 | c.2271G>T p.G757= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as COSV66135900; called by muse, mutect2
- HYAL3 | c.102G>A p.L34= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV56496841; called by muse, mutect2
- IL1R2 | c.225T>C p.A75= | Silent (SNP) | VAF 123/1097 reads (11%) | catalogued as COSV60205762; called by muse, mutect2, varscan2
- IREB2 | c.2223T>C p.H741= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs1041096900, COSV51920773; called by muse, mutect2
- KCNF1 | c.663G>A p.T221= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs751271962; called by mutect2, varscan2
- KCNH8 | c.267G>A p.E89= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV60457133, COSV60470172; called by muse, mutect2, varscan2
- OR1L4 | c.120G>A p.A40= | Silent (SNP) | VAF 17/413 reads (4%) | catalogued as rs1180879323, COSV52339752; called by muse, mutect2
- PCSK9 | c.636C>T p.D212= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs757510932; called by muse, mutect2
- POLR3B | c.2898C>T p.G966= | Silent (SNP) | VAF 47/798 reads (6%) | catalogued as COSV57276136; called by muse, mutect2
- PYGM | c.2091T>C p.N697= | Silent (SNP) | VAF 116/219 reads (53%) | catalogued as COSV51214920; called by muse, mutect2, varscan2
- RCN1 | c.384T>C p.D128= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV50014286; called by muse, mutect2
- RPL26L1 | c.318C>T p.I106= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV54199159; called by muse, mutect2, varscan2
- RREB1 | c.4728C>T p.D1576= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- RUNX2 | c.984G>A p.G328= | Silent (SNP) | VAF 19/283 reads (7%) | catalogued as rs1209757399, COSV61838940, COSV61843145; called by muse, mutect2
- SLC12A3 | c.324G>A p.R108= | Silent (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- STK35 | c.1491C>A p.S497= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV55689588; called by muse, mutect2, varscan2
- TAP1 | c.330C>T p.T110= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs746167727; called by muse, mutect2
- TBX21 | c.1377C>A p.G459= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV51595117; called by muse, mutect2, varscan2
- TMC2 | c.2349C>G p.S783= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV62649963; called by muse, mutect2, varscan2
- TRPC5 | c.1884T>C p.Y628= | Silent (SNP) | VAF 97/403 reads (24%) | catalogued as COSV53284736; called by muse, mutect2, varscan2
- ZBTB21 | c.1902C>A p.A634= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV60403222; called by muse, mutect2, varscan2
- ATP2B1 | c.3351+409C>T | Intron (SNP) | VAF 91/886 reads (10%) | catalogued as COSV99665266; called by muse, mutect2, varscan2
- MIR518E | n.21G>T | RNA (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- MIR668 | n.56G>A | RNA (SNP) | VAF 8/78 reads (10%) | catalogued as rs776614527; called by muse, mutect2, varscan2
- RPL31P57 | n.60G>C | RNA (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- TTN | c.10303+2241C>T | Intron (SNP) | VAF 17/109 reads (16%) | catalogued as COSV59899704; called by muse, mutect2, varscan2
